Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7P1, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7P1-01A (Primary Tumor).

[page 1 of 4]
Age: years Sex: Male

Date Printed:
Date Collected :
Date Received:
Accession No:
Physician:
Copy to:

Surgical Pathology Report

ICD-O-3
Mesothelioma, epithelioid NOS
9052/3
Site Pleura NOS
C38.4
JW 9/24/13

Clinical Information

year old male with mesothelioma; Left Pleurectomy PDT

Final Diagnosis

1. SKIN & SOFT TISSUE, "PREVIOUS BIOPSY SITE", FROZEN SECTION & TISSUE EXCISION:

Skin and subcutaneous soft tissue with scar, as well as focal polarizable foreign material surrounded by foreign body type giant cell reaction and chronic inflammation.
Negative for tumor.

2. SOFT TISSUE, "DEEPER EXCISION, PREVIOUS INCISION", FROZEN SECTION & TISSUE EXCISION:

Fibrous soft tissue and viable as well as necrotic skeletal muscle with only occasional small foci of polarizable foreign material, presence of predominant histiocytic and giant cell reaction with intermixed chronic inflammatory cells present. Granulation tissue reaction also focally present.
Negative for tumor.

3. RIB, EXCISION:

Benign lamellar bone and cartilage, fatty bone marrow with trilineage hematopoiesis.
Scant attached benign soft tissue present.
Negative for tumor.

4. LYMPH NODE, POSTERIOR INTERCOSTAL NODE, EXCISION:

Sections of lymph node, negative for tumor.
Fragment of benign skeletal muscle present.

5. PLEURA, LEFT THORACOTOMY w/ TUMOR DEBULKING - PARTIAL LEFT PLEURECTOMY:

Pleural soft tissues with malignant mesothelioma, epithelial type with focal sarcomatoid change, see Comment.

NO sarcomatoid focus in
tcga specimen, per TSS.
BWR

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Note

Immunohistochemical stains were performed on block 2A and show inflammatory cells (histiocytes) staining positive with CD68 and negative with AE1/3, confirming the above diagnosis.

Immunohistochemical stains were performed on block 5D with adequate controls (see Disclaimer) and show tumor cells staining positive for Calretinin, CK5/6, AE1/3, CK7, D2-40, and negative for Muc-31, TTF-1, CEA, CD15, CD30, PAX5,

Name:
MRN:

Page 1 of 3

[page 2 of 4]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Accession No: [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

CD21, LCA, WT-1. The focus of sarcomatoid change seen in slide 5D is negative for all immunohistochemical stains. The histologic and immunohistochemical findings support the above diagnosis.

Slide 5D with accompanying immunohistochemical slides was reviewed in consultation with [REDACTED] at the [REDACTED]

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the [REDACTED]. This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Specimen #3: According to Operative Report dated [REDACTED], the "seventh rib was resected"

Frozen Section Diagnosis

FS1: Skin and subcutaneous soft tissue, "previous biopsy site", FS: Representative sample of tissue with no tumor seen. Skin and subcutaneous soft tissue with scar, focal chronic inflammation and giant cell reaction.

FS2A, 2B: Muscle and soft tissue, "Deeper excision at site of previous incision", FS: Representative sample of tissue with viable as well as necrotic skeletal muscle, granulation tissue formation, predominant chronic inflammation and giant cell reaction present. No tumor seen.

Gross Description

The specimen is received in five parts in a container labeled with the patient's name and medical record number.

Specimen #1 is received fresh for frozen section and designated "previous biopsy site" and consists of a 6.6 x 1.6 cm skin ellipse excised to a depth of 1.1 cm. The skin surface is tan white, wrinkled and displays an ill-defined paracentral linear 3.3 cm long scar. The deep surface is inked black. A representative section is submitted for frozen section, and the frozen section control is submitted in cassette 1A. Additional representative sections are submitted in cassettes 1B and 1C.

Name: [REDACTED]
MRN: [REDACTED]

[page 3 of 4]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected:
Date Received:
Accession No.: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #2 is received fresh for frozen section and designated "deeper excision, previous incision" and consists of a 6.5 x 1.5 x 1.4 cm irregular portion of tan red to tan yellow, rubbery coarsely lobulated soft tissue. Sectioning reveals red brown to tan white, focally dense cut surfaces. Representative sections are submitted for frozen section, and the frozen section control is submitted in cassettes 2A and 2B. Additional representative sections are submitted in cassettes 2C and 2D.

Specimen #3 is received in formalin and designated "rib" and consists of three cylindrical fragments of firm bone ranging from 5.5 to 6.4 cm in length, grossly consistent with a fragmented rib. Sectioning reveals tan red, firm and trabeculated cut surfaces with no discrete masses or lesions grossly identified. A representative section is submitted in cassette 3A following decalcification.

Specimen #4 is received in formalin and designated "posterior intercostal node" and consists of three tan yellow to gray black, nodular soft tissue fragments measuring 0.4, 0.5 and 0.6 cm in greatest dimension. The specimen is submitted in toto in cassette 4A.

Specimen #5 is received in formalin and designated "pleura" and consists of a 111.5 gram aggregate of three irregular fragments of tan white to tan gray, indurated soft tissue fragments ranging from 7.5 to 8.7 cm in greatest dimension. There are focal areas of attached yellow tan, coarsely lobulated adipose tissue. Sectioning reveals diffusely, dense cut surfaces. The largest fragment is sectioned to reveal tan white, indurated gritty cut surfaces which are intermingled with the yellow tan adipose tissue. Representative sections from each fragment are submitted in cassettes 5A through 5E with the largest fragment in relation to the attached adipose tissue submitted in cassettes 5D and 5E.

Dictated by:

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

Page 3 of 3

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Mesothelioma -	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form		Provide the tumor identifier documented on the initial case quality control form for this case.
Pathologic Diagnosis Provided on Initial Pathology Report	epithelial with focal sarcomatoid change	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF	epithelial	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	Submitted specimen histology is epethelioid, no sarcomatoid focus seen; Clinical pathology report indicates the frozen specimen was epethelioid with a focus of sarcomatoid changes.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director	Provide the name of the pathologist who reviewed this case for TCGA.	

Source: NCI Genomic Data Commons file edee9626-1e9c-45f2-a5b6-a601abc68c5b (TCGA-TS-A7P1.0FAC8AE9-5E06-44F7-9327-0A3DB528C946.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).